Somatic mutation profile of tumor specimen TARGET-20-PANLJN-09A (aliquot TARGET-20-PANLJN-09A-03D) from TARGET case TARGET-20-PANLJN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.9 years (6,524 days).
Specimen TARGET-20-PANLJN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e985010-f0bf-4672-8a73-03a007c140fc.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANLJN-14A (Bone Marrow Normal), aliquot TARGET-20-PANLJN-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52ec05e9-eb2c-4cbf-b708-e33fe623d540

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 38/240 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCCGG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 21/65 reads (32%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by mutect2, pindel, varscan2
- GATA2 | c.1087_1088insGGA p.R362dup | In Frame Ins (INS) | VAF 56/117 reads (48%) | called by mutect2, pindel, varscan2
- BSN | c.*806G>A | 3'UTR (SNP) | VAF 14/309 reads (5%) | catalogued as rs1274459803; called by muse, mutect2
